Somatic mutation profile of tumor specimen TCGA-FY-A4B3-01A (aliquot TCGA-FY-A4B3-01A-11D-A23U-08) from TCGA case TCGA-FY-A4B3, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 51.9 years (18,969 days).
Specimen TCGA-FY-A4B3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22c21207-198a-4ff3-bbba-6e80580600f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A4B3-10A (Blood Derived Normal), aliquot TCGA-FY-A4B3-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/041c1056-f2f8-408b-ae6c-9071f57b9bff

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDH6 | c.1046C>A p.A349D | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54071959, COSV54072896; called by muse, mutect2, varscan2
- DEUP1 | c.51G>C p.E17D | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53213250; called by muse, varscan2
- EIF3E | c.1260G>A p.M420I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV55203610; called by muse, mutect2, varscan2
- KCNC3 | c.1192C>G p.L398V | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV65387427, COSV65387843; called by muse, mutect2
- PPL | c.3545C>T p.P1182L | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52169152; called by muse, mutect2, varscan2
- ADAMTS16 | c.2028G>A p.Q676= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV56993536; called by muse, mutect2, varscan2
- AGPAT2 | c.108G>T p.L36= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV65465155; called by muse, mutect2, varscan2
- SPACA9 | c.402C>T p.Y134= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs537630425, COSV53768287; called by muse, mutect2, varscan2
- PRR12 | chr19:49594612 A>G | 5'Flank (SNP) | VAF 17/55 reads (31%) | catalogued as COSV55870577; called by muse, mutect2, varscan2
